Surgical pathology report (de-identified scan), TCGA case TCGA-29-1695, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1695-01A (Primary Tumor).

[page 1 of 2]
CLINICAL HISTORY:

Abdominal/pelvic swelling [REDACTED]

TCGA-29-1695

GROSS EXAMINATION:

A. "Omentum (AF1)". Received fresh for frozen section is a 22 x 15 x 6 cm aggregate of yellow-tan tissue. The tissue consists of approximately 20% yellow, lobulated omentum and the rest consists of firm, tan masses. A representative section was frozen as AF1 and the frozen section remnant was submitted in block A1. Representative sections of the masses with some omentum are placed in blocks A2-5.

B. "Right tube and ovary". Received fresh and placed in formalin is a 5.3 gram, 3 x 1.1 x 1.1 cm ovary with attached 2.2 x 0.3 cm fallopian tube and soft tissue. Tube and ovary are grossly unremarkable and representative sections are placed in B1.

C. "Left tube and ovary". Received fresh and placed in formalin is a 9.8 gram, 3 x 1.5 x 0.6 cm ovary with attached 3 x 0.3 cm fallopian tube and soft tissue. The ovary and fallopian tube are grossly unremarkable and representative sections are placed in block C1.

D. "Omentum". Received fresh and placed in formalin is a 14 x 9.5 x 5 cm aggregate of yellow-tan tissue. The specimen is composed of approximately 20% yellow lobulated omentum and the rest of the tissue is firm tan tumor. There are focal areas of necrosis within the tumors. Representative sections are placed in blocks D1-3.

[REDACTED]

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1-metastatic carcinoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

IMMUNOHISTOCHEMICAL FINDINGS:

Sections from the paraffin block are cut at 4-5 micrometers, placed on positively-charged glass slides, deparaffinized in organic solvents, treated with methanolic H2O2 to quench endogenous peroxidase activity, and rehydrated. Sections are treated with primary antibodies to detect the antigen(s) in question, or with non-immune rabbit immunoglobulin(s) or mouse isotype(s) as a negative control; appropriate positive tissue controls are also tested. Sections are sequentially reacted with biotinylated secondary antibody and with streptavidin or avidin-biotin-complex labeled with horseradish peroxidase. Immunoreactivity is visualized using diaminobenzidine as the chromogen. Counterstaining is performed. The results are as follows:

Tumor cells are diffusely positive with Ber-EP4 and CA-125, and focally positive with CK5/6. Tumor cells are negative with chromogranin, synaptophysin, calretinin, and CD30.

DIAGNOSIS:

A. "OMENTUM" (OMENTECTOMY):

SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED, IN FIBROADIPOSE TISSUE. (SEE NOTE).

[REDACTED]

[page 2 of 2]
B. "RIGHT FALLOPIAN TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY AND FALLOPIAN TUBE, NO TUMOR PRESENT.

C. "LEFT FALLOPIAN TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

TYPE: SEROUS ADENOCARCINOMA. SEE NOTE.

FIGO GRADE: 3, POORLY DIFFERENTIATED.

TUMOR SIZE: 1.5 X 1.0 X 1.0 CM.

SEROSA: NOT INVOLVED.

ADDITIONAL FINDINGS: FALLOPIAN TUBE, NO TUMOR PRESENT.

TCGA-29-1695

D. "OMENTUM" (OMENTECTOMY):

SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED, IN FIBROADIPOSE TISSUE.

NOTE: The size of the intraparenchymal tumor in the left ovary, immunohistochemical profile, and pattern of spread are consistent with an ovarian primary. The case was discussed with the gynecologic oncology fellow.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 881bd0a4-6441-412e-ad74-6206ce3ddc71 (TCGA-29-1695.136A4380-2A2A-489F-8675-886E876F17F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).